Somatic mutation profile of cancer-model specimen HCM-CSHL-0176-C25-85A (3D Organoid; aliquot HCM-CSHL-0176-C25-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0176-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.0 years (21,917 days).
Specimen HCM-CSHL-0176-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4c39f8f-13c6-4120-9f3e-6bd432bc42f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0176-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0176-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cbb2112-d361-4081-8326-4bd8527dc150

The open-access MAF lists 75 somatic variants for this specimen: 44 protein-altering or splice-affecting, 19 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 19, Intron 5, RNA 3, Nonsense Mutation 3, 5'Flank 2, Splice Site 2, 3'UTR 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 159/349 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 340/342 reads (99%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 175/308 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs368104861; called by muse, mutect2, varscan2
- ABCC9 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 140/329 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.495); catalogued as rs143685061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs770183441, COSV54443001; called by muse, mutect2, varscan2
- CATSPER3 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 114/243 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1252607302; called by muse, mutect2, varscan2
- CELF4 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 116/229 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs150441111, COSV100612162; called by muse, mutect2, varscan2
- COL5A3 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs770509108, COSV53415167; called by muse, mutect2, varscan2
- CSRP2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 139/139 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs766825277; called by muse, mutect2, varscan2
- CTIF | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1268738342, COSV56486914; called by muse, mutect2, varscan2
- DDN | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1009416068, COSV100304863; called by muse, mutect2, varscan2
- DHTKD1 | c.2540A>G p.Q847R | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as rs1033452671, COSV53801640; called by muse, mutect2, varscan2
- DLG2 | c.1398G>C p.Q466H | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs757315881, COSV54683185, COSV54685776; called by muse, mutect2
- DLGAP3 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 233/440 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as rs140339373, COSV52395991, COSV52397212; called by muse, mutect2, varscan2
- G2E3 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.994); catalogued as rs749078341; called by muse, mutect2, varscan2
- KIF2B | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 90/135 reads (67%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1159894082, COSV52126988; called by muse, mutect2, varscan2
- MPP6 | c.308G>C p.C103S | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1452850072; called by muse, mutect2, varscan2
- NLRP5 | c.3544G>A p.V1182I | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as rs779422093, COSV101173776, COSV66766314; called by muse, mutect2
- NPTX2 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 198/506 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377548219; called by muse, mutect2, varscan2
- OR13A1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 108/108 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs201230704, COSV65572495; called by muse, mutect2, varscan2
- PAK6 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 90/179 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs777888104; called by muse, mutect2, varscan2
- PIEZO2 | c.2926G>A p.A976T | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1331740910; called by muse, mutect2, varscan2
- PLEKHN1 | c.1888C>T p.P630S (on ENST00000379409; = p.P578S on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as rs1289182988; called by muse, mutect2, varscan2
- PRKCG | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 372/760 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs751774653, COSV54725976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF4 | c.3154C>T p.R1052* | Nonsense Mutation (SNP) | VAF 147/339 reads (43%) | catalogued as COSV53334463; called by muse, mutect2, varscan2
- TNPO2 | c.2417C>T p.T806M (on ENST00000425528 / NM_001382240.1; = p.T796M on NM_013433.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/220 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV63509122; called by muse, mutect2, varscan2
- TRIOBP | c.6778G>A p.G2260S (on ENST00000644935 / NM_001039141.3; = p.G547S on NM_007032.5) | Missense Mutation (SNP) | VAF 354/768 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765357483; called by muse, mutect2, varscan2
- VWDE | c.4762A>G p.R1588G | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV51727970; called by muse, mutect2
- ZSCAN18 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); catalogued as COSV53729637, COSV99559285; called by muse, mutect2, varscan2
- AP4M1 | c.557A>T p.E186V | Missense Mutation (SNP) | VAF 484/1428 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDH9 | c.2120G>T p.W707L | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CDX2 | c.104dup p.Q36Afs*192 | Frame Shift Ins (INS) | VAF 111/265 reads (42%) | called by mutect2, pindel, varscan2
- DAAM1 | c.1507C>G p.Q503E | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GTF3C1 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- HPN | c.620+4_620+17del p.X207_splice | Splice Site (DEL) | VAF 19/216 reads (9%) | called by mutect2, pindel
- MAP1A | c.2502G>C p.E834D | Missense Mutation (SNP) | VAF 176/379 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- NKAPD1 | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 113/299 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR13H1 | c.582T>G p.N194K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2
- RBM10 | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 286/286 reads (100%) | called by muse, mutect2, varscan2
- SIGIRR | c.603C>G p.D201E | Missense Mutation (SNP) | VAF 120/239 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- STIP1 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 137/231 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TADA2B | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 150/336 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TSPAN19 | c.71T>C p.L24P | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ZNF510 | c.256+1G>C p.X86_splice | Splice Site (SNP) | VAF 92/92 reads (100%) | called by muse, mutect2, varscan2
- A1BG | c.1128C>T p.Y376= | Silent (SNP) | VAF 182/355 reads (51%) | catalogued as rs746018515, COSV99568805; called by muse, mutect2, varscan2
- CSMD1 | c.6831C>T p.F2277= (on ENST00000520002; = p.F2276= on NM_033225.6) | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs371661443, COSV59378788; called by muse, mutect2, varscan2
- EGFLAM | c.2010C>T p.H670= | Silent (SNP) | VAF 95/192 reads (49%) | catalogued as rs199798525, COSV59292831; called by muse, mutect2, varscan2
- EPS8L1 | c.1920C>T p.R640= (on ENST00000201647 / NM_133180.3; = p.R513= on NM_017729.3) | Silent (SNP) | VAF 84/160 reads (53%) | catalogued as COSV52381421; called by muse, mutect2, varscan2
- EXD3 | c.2205C>T p.Y735= | Silent (SNP) | VAF 11/262 reads (4%) | catalogued as rs1450205117; called by muse, mutect2
- GRIN2A | c.684G>A p.L228= | Silent (SNP) | VAF 229/508 reads (45%) | called by muse, mutect2, varscan2
- JCAD | c.2073A>G p.T691= | Silent (SNP) | VAF 223/377 reads (59%) | called by muse, mutect2, varscan2
- KCNT1 | c.1173G>A p.T391= (on ENST00000488444; = p.T410= on NM_020822.3) | Silent (SNP) | VAF 172/172 reads (100%) | catalogued as rs778178642, COSV53703072; called by muse, mutect2, varscan2
- KMT2A | c.1257G>A p.S419= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as rs141004205; called by muse, mutect2, varscan2
- MCC | c.1659A>C p.T553= | Silent (SNP) | VAF 79/172 reads (46%) | called by muse, mutect2, varscan2
- MN1 | c.1158G>A p.A386= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as rs1259652005; called by muse, mutect2, varscan2
- MYH3 | c.483C>T p.N161= | Silent (SNP) | VAF 249/250 reads (100%) | catalogued as rs202066674; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYOD1 | c.909C>T p.A303= | Silent (SNP) | VAF 74/121 reads (61%) | catalogued as rs545519590; called by muse, mutect2, varscan2
- NRXN1 | c.744C>T p.T248= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs202043138, COSV68006109, COSV68044503; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- OR51E1 | c.888G>A p.V296= | Silent (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- PCLO | c.1650G>A p.S550= | Silent (SNP) | VAF 1067/1374 reads (78%) | catalogued as rs780915122; called by muse, mutect2, varscan2
- PKD1 | c.9414G>A p.V3138= | Silent (SNP) | VAF 124/281 reads (44%) | called by muse, mutect2, varscan2
- TSPEAR | c.1317G>A p.A439= | Silent (SNP) | VAF 32/156 reads (21%) | catalogued as rs782043381, COSV59973686; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF281 | c.1180T>C p.L394= | Silent (SNP) | VAF 98/212 reads (46%) | catalogued as rs1477938775; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916002 G>A | 5'Flank (SNP) | VAF 88/174 reads (51%) | catalogued as rs1160280833, COSV100388235; called by muse, mutect2, varscan2
- CDH4 | c.170-24701C>A | Intron (SNP) | VAF 193/377 reads (51%) | called by muse, mutect2, varscan2
- CTNNB1 | c.13+9C>T | Intron (SNP) | VAF 118/214 reads (55%) | called by muse, mutect2, varscan2
- ENO1 | c.1176+17C>T | Intron (SNP) | VAF 75/167 reads (45%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1447C>T | RNA (SNP) | VAF 106/1158 reads (9%) | catalogued as rs777991147; called by mutect2, varscan2
- MCF2L | c.3166-42C>T | Intron (SNP) | VAF 157/300 reads (52%) | catalogued as rs764138312; called by muse, mutect2, varscan2
- PEG10 | c.*128C>T | 3'UTR (SNP) | VAF 99/488 reads (20%) | called by muse, mutect2, varscan2
- PSMC3IP | chr17:42577766 G>A | 5'Flank (SNP) | VAF 107/317 reads (34%) | called by muse, mutect2, varscan2
- RASA4CP | n.522C>G | RNA (SNP) | VAF 245/626 reads (39%) | catalogued as rs1405430735; called by muse, mutect2, varscan2
- RBM8B | n.113G>A | RNA (SNP) | VAF 166/552 reads (30%) | catalogued as rs773963545; called by muse, mutect2
- SEC11C | c.-32C>T | 5'UTR (SNP) | VAF 42/83 reads (51%) | catalogued as rs949843594; called by muse, mutect2, varscan2
- SYN1 | c.774+19G>C | Intron (SNP) | VAF 14/312 reads (4%) | called by muse, mutect2
